Somatic mutation profile of tumor specimen TCGA-60-2704-01A (aliquot TCGA-60-2704-01A-11D-2042-08) from TCGA case TCGA-60-2704, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.7 years (26,927 days).
Specimen TCGA-60-2704-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29289d6c-c5e9-4357-bf46-094be5a77a35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2704-11A (Solid Tissue Normal), aliquot TCGA-60-2704-11A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/903221bc-0d18-42a6-b78f-5eee08ab2050

The open-access MAF lists 197 somatic variants for this specimen: 140 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 52, Nonsense Mutation 5, Splice Site 3, RNA 3, Frame Shift Del 2, Translation Start Site 2, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.5672-1G>C p.X1891_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as rs1555395849, CS117737, COSV100355175, COSV57320011; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV100718171; called by muse, mutect2
- ACSBG1 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51905547; called by muse, mutect2
- ADCY10 | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100896878; called by muse, mutect2
- ADGRE1 | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99165330; called by muse, mutect2, varscan2
- ADGRG5 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs748794008, COSV61083056; called by muse, mutect2, varscan2
- AFF3 | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.694); catalogued as COSV100418932; called by muse, mutect2, varscan2
- ALMS1 | c.4946G>T p.G1649V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV100042540; called by muse, mutect2, varscan2
- ANK3 | c.2105A>G p.H702R | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780124; called by muse, mutect2, varscan2
- ARHGAP21 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100256243, COSV57603838; called by muse, mutect2, varscan2
- ARHGAP22 | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99985313; called by muse, mutect2, varscan2
- ARHGAP35 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68329306, COSV68332376; called by muse, mutect2
- ARRB2 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99347086; called by muse, mutect2, varscan2
- ASB5 | c.670+1G>C p.X224_splice | Splice Site (SNP) | VAF 6/43 reads (14%) | catalogued as rs1395929519, COSV99641696; called by muse, mutect2
- ATP11C | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV100557967; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1333A>C p.T445P | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV99369437; called by muse, mutect2, varscan2
- C3AR1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99368581; called by muse, mutect2, varscan2
- CACNA1A | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100802490; called by muse, mutect2
- CACNA1A | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100802491; called by muse, mutect2
- CADPS | c.709T>C p.W237R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99338454; called by muse, mutect2, varscan2
- CCDC184 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100343976; called by muse, mutect2, varscan2
- CCDC83 | c.1079A>G p.K360R (on ENST00000342404 / NM_001286159.2; = p.K391R on NM_173556.5) | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99721707; called by muse, mutect2
- CDH12 | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1324348982, COSV66451249; called by muse, mutect2, varscan2
- CDH12 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101202600; called by muse, mutect2, varscan2
- CHCHD6 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99336269; called by muse, mutect2, varscan2
- CIB1 | c.519C>G p.F173L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100153322; called by muse, mutect2, varscan2
- COL22A1 | c.2194G>A p.G732S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100278659; called by muse, mutect2, varscan2
- CPT1C | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99773480; called by muse, mutect2
- CSMD2 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs901155048, COSV53897001; called by muse, mutect2, varscan2
- CSMD3 | c.6058A>G p.S2020G (on ENST00000297405 / NM_001363185.1; = p.S1916G on NM_052900.3) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99835216; called by muse, mutect2, varscan2
- CTAG2 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.005); catalogued as COSV99909000; called by muse, mutect2, varscan2
- CTSF | c.277A>T p.M93L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100074295; called by muse, mutect2, varscan2
- CXXC1 | c.1207C>A p.R403S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763874891, COSV53276153, COSV99496408; called by muse, mutect2, varscan2
- DAGLA | c.2641G>C p.E881Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV99944403; called by muse, mutect2, varscan2
- DPRX | c.141A>T p.K47N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.619); catalogued as COSV100934083; called by muse, mutect2, varscan2
- ENPP3 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs772528200, COSV100717329; called by muse, mutect2, varscan2
- EPRS1 | c.1420T>C p.F474L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100859396; called by muse, mutect2, varscan2
- EXOSC7 | c.311A>T p.E104V | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV99652026; called by muse, mutect2, varscan2
- FAXC | c.1182T>G p.D394E | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV101067153; called by muse, mutect2
- FOXJ1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99486999; called by muse, mutect2, varscan2
- FRAS1 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV53601059, COSV53649616; called by mutect2, varscan2
- GABRG1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs764481527, COSV54956012; called by muse, mutect2
- GJA8 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99569420; called by muse, mutect2, varscan2
- GNB2 | c.431-1G>C p.X144_splice | Splice Site (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99309435; called by muse, mutect2
- GPATCH1 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as COSV99404052; called by muse, mutect2, varscan2
- HCN1 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100300372, COSV57538426; called by muse, mutect2, varscan2
- HEG1 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); catalogued as COSV100230539; called by muse, mutect2
- HERC1 | c.3524C>T p.T1175M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs763817683, COSV101496588; called by muse, mutect2, varscan2
- HIGD1B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs758110221, COSV53656265; called by muse, mutect2, varscan2
- HSP90B1 | c.1969A>C p.N657H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs3209749, COSV100236546; called by muse, mutect2, varscan2
- IFT81 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99656012; called by muse, mutect2, varscan2
- IPP | c.1711A>G p.N571D | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV100739573; called by muse, mutect2, varscan2
- IRS2 | c.926C>G p.S309W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101019118; called by muse, mutect2
- JMJD1C | c.2969G>T p.C990F | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100550583; called by muse, mutect2, varscan2
- KCND2 | c.251T>C p.F84S | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100476016; called by muse, mutect2, varscan2
- KCNT1 | c.2547C>G p.S849R (on ENST00000488444; = p.S868R on NM_020822.3) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99705825; called by muse, mutect2, varscan2
- KIAA1109 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV99164118; called by muse, mutect2, varscan2
- KNL1 | c.4741C>G p.H1581D (on ENST00000346991 / NM_170589.5; = p.H1555D on NM_144508.5) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100706531; called by muse, mutect2, varscan2
- LAIR1 | c.232A>T p.S78C | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV100479647, COSV57308427; called by muse, varscan2
- LAIR1 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100479649; called by muse, varscan2
- LAPTM5 | c.386C>A p.A129D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.077); catalogued as COSV99612406; called by muse, mutect2, varscan2
- LCE2B | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.017); catalogued as COSV100909314; called by muse, mutect2, varscan2
- LRRC6 | c.1145-4G>A | Splice Region (SNP) | VAF 8/66 reads (12%) | catalogued as COSV51537739; called by muse, mutect2
- LRRC7 | c.3170A>T p.Q1057L (on ENST00000651989 / NM_001370785.2; = p.Q1024L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV99227131; called by muse, mutect2, varscan2
- MAGEB6B | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs763403418; called by muse, mutect2, varscan2
- MAGED2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99514570; called by muse, mutect2, varscan2
- MED29 | c.508G>A p.A170T (on ENST00000615911; = p.A149T on NM_017592.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.146); catalogued as rs1342109038, COSV100219186; called by muse, mutect2, varscan2
- MME | c.855T>A p.N285K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs1434664230, COSV100852406; called by muse, mutect2, varscan2
- MRC2 | c.3934G>A p.V1312M | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100316282; called by muse, mutect2, varscan2
- MYH2 | c.3928G>A p.G1310S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV99820212; called by muse, mutect2, varscan2
- MYH2 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99820214; called by muse, mutect2, varscan2
- MYH8 | c.1790T>A p.L597Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101238416; called by muse, mutect2, varscan2
- NCOA6 | c.2158C>G p.Q720E | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV62863465; called by muse, mutect2
- NEB | c.10631C>T p.P3544L | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200557002, COSV51429766; called by muse, mutect2, varscan2
- NF2 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as CX087779, COSV100098465; called by muse, mutect2, varscan2
- NLRP12 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1362190303, COSV100145311; called by muse, mutect2
- NPAS4 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV60652299; called by muse, mutect2, varscan2
- NRP2 | c.2045A>G p.D682G | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.386); catalogued as COSV99784639; called by muse, mutect2, varscan2
- OR13C8 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV100622978; called by muse, mutect2, varscan2
- OR2A14 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV101376471; called by muse, mutect2, varscan2
- OR4L1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs778355002, COSV59851452; called by muse, mutect2, varscan2
- OR7C2 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.027); catalogued as rs1174243683, COSV99934531; called by muse, mutect2, varscan2
- OR8G5 | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100422437; called by muse, mutect2, varscan2
- OXR1 | c.2094C>G p.D698E (on ENST00000442977 / NM_001198532.1; = p.D670E on NM_018002.3) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99861020; called by muse, mutect2, varscan2
- PANX3 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99421510; called by muse, mutect2, varscan2
- PAOX | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1472318687, COSV53371964; called by muse, mutect2
- PARP4 | c.3325A>T p.T1109S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV101131660; called by muse, mutect2, varscan2
- PCDHGA11 | c.2407G>A p.G803S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.04); catalogued as COSV99538888; called by muse, mutect2
- PDS5B | c.3949A>C p.K1317Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100220989; called by muse, mutect2, varscan2
- PGM3 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs763858041, COSV99392384; called by muse, mutect2
- PI4KA | c.1488C>G p.F496L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV55411532, COSV99746383; called by muse, mutect2, varscan2
- PIGF | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as rs752017440, COSV99482746; called by muse, mutect2, varscan2
- PLXNC1 | c.2854C>A p.P952T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.666); catalogued as COSV99313180; called by muse, mutect2, varscan2
- POLD3 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99738043; called by muse, mutect2, varscan2
- PTEN | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64288485, COSV64297388; called by muse, mutect2, varscan2
- PTPRC | c.2390T>C p.L797S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100722691; called by muse, mutect2, varscan2
- PTPRO | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55506575, COSV99840587; called by muse, mutect2, varscan2
- PTPRR | c.194G>T p.S65I | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV51736351, COSV99317610; called by muse, mutect2, varscan2
- PTPRS | c.477C>A p.S159R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV53640224, COSV99510745; called by muse, mutect2, varscan2
- PWWP3A | c.301G>C p.E101Q (on ENST00000627377; = p.E100Q on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as COSV100262018; called by muse, mutect2, varscan2
- PXDNL | c.2869G>T p.G957W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62478360; called by muse, varscan2
- RASA1 | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.161); catalogued as COSV99169843; called by muse, mutect2, varscan2
- RIMS1 | c.2873G>T p.R958L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99327156; called by mutect2, varscan2
- RIMS1 | c.3715C>A p.P1239T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99327158; called by muse, mutect2, varscan2
- RIPK2 | c.402C>G p.Y134* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV99609898; called by muse, mutect2, varscan2
- ROR2 | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100995835; called by muse, mutect2, varscan2
- RP1L1 | c.6200C>A p.A2067D | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.006); catalogued as COSV101223046; called by muse, mutect2
- RPH3A | c.1034G>C p.R345T (on ENST00000389385 / NM_001143854.2; = p.R341T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV101231825, COSV66993513; called by muse, mutect2, varscan2
- RPL3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV53366784; called by muse, mutect2
- RRAS | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs767209383, COSV99882057; called by muse, mutect2, varscan2
- SERPINB9 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs144457124; called by muse, mutect2, varscan2
- SHOX | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1384656900, COSV61861404; called by muse, mutect2, varscan2
- SLC17A9 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 18/198 reads (9%) | catalogued as rs17856725, COSV100947847; called by muse, mutect2
- SLC25A53 | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.308); catalogued as COSV100656002; called by muse, mutect2, varscan2
- SPEF2 | c.4036G>A p.V1346I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100607494; called by muse, mutect2, varscan2
- SYT5 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62831546; called by muse, mutect2
- TAF4 | c.3172G>A p.V1058I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs970650199, COSV99434240; called by muse, mutect2, varscan2
- TAF5L | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99273203; called by muse, varscan2
- TASOR | c.1976G>A p.R659K (on ENST00000355628 / NM_001365636.2; = p.R263K on NM_015224.3) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100843571; called by muse, mutect2, varscan2
- TBC1D10A | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99304675; called by muse, mutect2
- TBP | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57831586; called by muse, mutect2, varscan2
- TENM1 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.413); catalogued as rs1435103115, COSV64438057; called by muse, mutect2, varscan2
- TENM3 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); catalogued as rs200278921, COSV69298547; called by muse, mutect2, varscan2
- TMEM38B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV101016341, COSV65950588; called by muse, mutect2, varscan2
- TMPRSS15 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175054408, COSV99518014; called by muse, mutect2, varscan2
- TP53 | c.562_563del p.L188Gfs*20 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV53331740; called by mutect2, pindel, varscan2
- TRAPPC8 | c.2310G>C p.L770F | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV99351296; called by muse, mutect2, varscan2
- TRPC5 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99461066; called by muse, mutect2, varscan2
- TTN | c.27368G>A p.G9123D (on ENST00000591111; = p.G8196D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | PolyPhen probably damaging (0.959); catalogued as COSV100614414; called by muse, mutect2
- TTN | c.21430G>C p.D7144H (on ENST00000591111; = p.D6217H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | PolyPhen possibly damaging (0.741); catalogued as COSV100614416; called by muse, mutect2
- TUBA3C | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 35/159 reads (22%) | catalogued as COSV101262797, COSV67139143; called by muse, mutect2, varscan2
- TUBB4A | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99900007; called by muse, mutect2, varscan2
- TYK2 | c.3481A>G p.T1161A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs905890917, COSV99314779; called by muse, mutect2, varscan2
- ZAN | c.7745A>T p.D2582V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV100769750; called by muse, mutect2, varscan2
- ZBBX | c.807G>A p.W269* | Nonsense Mutation (SNP) | VAF 20/178 reads (11%) | catalogued as COSV100284079; called by muse, mutect2, varscan2
- ZFYVE26 | c.6661G>A p.E2221K | Missense Mutation (SNP) | VAF 90/475 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100720447; called by muse, mutect2, varscan2
- ZNF34 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100603294; called by muse, mutect2, varscan2
- IGHV6-1 | c.122C>A p.T41N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- IGLV5-48 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- TTC37 | c.3541del p.Q1181Kfs*36 | Frame Shift Del (DEL) | VAF 21/139 reads (15%) | called by mutect2, pindel, varscan2
- ADCY4 | c.1866C>G p.L622= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100156593; called by muse, mutect2, varscan2
- ALPK3 | c.2937G>T p.G979= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV99360975; called by muse, mutect2
- AOC3 | c.1476G>A p.T492= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs777738900, COSV53827433; called by muse, mutect2, varscan2
- ARHGAP31 | c.2247C>T p.L749= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs1365739496, COSV99957160; called by muse, mutect2, varscan2
- ASPM | c.8493A>G p.R2831= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1275270365, COSV99660415; called by muse, mutect2
- CD163L1 | c.3933T>C p.D1311= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV58021617; called by muse, mutect2, varscan2
- CD4 | c.990G>A p.V330= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99163781; called by muse, mutect2, varscan2
- CDC27 | c.81C>A p.L27= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99294909; called by muse, mutect2, varscan2
- CDK2 | c.648T>C p.F216= | Silent (SNP) | VAF 42/260 reads (16%) | catalogued as COSV99906732; called by muse, mutect2, varscan2
- CNST | c.1578G>T p.V526= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV100830061; called by muse, mutect2, varscan2
- CTSG | c.693C>A p.V231= | Silent (SNP) | VAF 41/206 reads (20%) | catalogued as COSV53537016; called by muse, mutect2, varscan2
- CUX2 | c.4338C>T p.H1446= | Silent (SNP) | VAF 30/172 reads (17%) | catalogued as COSV99919740; called by muse, mutect2, varscan2
- CYRIA | c.354C>A p.T118= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100838404; called by muse, mutect2, varscan2
- DBH | c.294A>G p.A98= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99708047; called by muse, mutect2, varscan2
- DHH | c.696C>A p.G232= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99908845; called by muse, mutect2, varscan2
- DISP1 | c.1803G>A p.L601= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV99451122; called by muse, mutect2, varscan2
- DLX6 | c.735G>A p.S245= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs760073542, COSV99142177; called by mutect2, varscan2
- DPP10 | c.117G>T p.L39= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV100065852; called by muse, mutect2, varscan2
- DPP6 | c.897G>A p.K299= (on ENST00000377770 / NM_001364500.2; = p.K237= on NM_001936.5) | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV100125798; called by muse, mutect2
- FAM53A | c.51C>G p.L17= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV100357016; called by muse, mutect2, varscan2
- GPAA1 | c.822C>T p.P274= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs368735326, COSV60156076; called by muse, mutect2, varscan2
- GTPBP3 | c.1386G>T p.R462= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100258903; called by muse, mutect2, varscan2
- HAO1 | c.873C>T p.D291= | Silent (SNP) | VAF 65/204 reads (32%) | catalogued as rs770281323, COSV66490893; called by muse, mutect2, varscan2
- HCN1 | c.2541G>C p.S847= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV57502512; called by muse, mutect2, varscan2
- ITPRID1 | c.2445C>T p.C815= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV100086485; called by muse, mutect2, varscan2
- KIAA1210 | c.2499C>T p.D833= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101274167; called by muse, mutect2
- KIF20B | c.2244G>A p.L748= (on ENST00000371728 / NM_001284259.2; = p.L708= on NM_016195.4) | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99590064; called by muse, varscan2
- LY86 | c.87A>G p.T29= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100041033; called by muse, mutect2, varscan2
- MRPL32 | c.249T>C p.N83= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs373928165; called by muse, mutect2, varscan2
- NCOA6 | c.2571C>T p.F857= | Silent (SNP) | VAF 7/152 reads (5%) | catalogued as COSV100750066; called by muse, mutect2
- NEXMIF | c.2436A>T p.G812= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99280899; called by muse, mutect2, varscan2
- NFE2 | c.919C>A p.R307= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100380757; called by muse, mutect2, varscan2
- OR52I2 | c.478C>T p.L160= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100442919; called by muse, mutect2, varscan2
- OR5AC2 | c.9A>T p.I3= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100684393; called by muse, varscan2
- PFDN6 | c.87G>A p.G29= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs777352844, COSV101004791; called by muse, mutect2, varscan2
- PSAPL1 | c.378G>A p.P126= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs772342346, COSV100040512; called by mutect2, varscan2
- RDH8 | c.228G>A p.L76= (on ENST00000651512; = p.L56= on NM_015725.4) | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99408656; called by muse, mutect2
- RIMS1 | c.3714G>A p.A1238= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs373917034; called by muse, mutect2, varscan2
- SERAC1 | c.1029C>A p.I343= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100894838; called by muse, mutect2, varscan2
- SHROOM3 | c.33T>C p.P11= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2
- SLCO1B1 | c.1362A>G p.V454= | Silent (SNP) | VAF 7/109 reads (6%) | catalogued as COSV99918548; called by muse, mutect2
- SPIDR | c.84A>G p.P28= | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- SPRYD7 | c.423A>G p.V141= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100709838; called by mutect2, varscan2
- SYNE2 | c.19221G>A p.E6407= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV100647741; called by muse, mutect2, varscan2
- TPO | c.2487C>T p.Y829= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs774085308, COSV100221133; called by muse, mutect2, varscan2
- TRIM69 | c.945G>A p.Q315= (on ENST00000329464 / NM_182985.5; = p.Q156= on NM_080745.5) | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV100274282; called by muse, mutect2, varscan2
- UBB | c.655C>T p.L219= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100141657; called by muse, mutect2, varscan2
- UBE2O | c.3828C>T p.F1276= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV60067700; called by muse, mutect2, varscan2
- USH2A | c.7197C>T p.I2399= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as rs1305453013, COSV100235280; ClinVar: likely benign; called by muse, mutect2
- ZNF280A | c.363T>C p.S121= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs1030746632, COSV100131063; called by muse, mutect2, varscan2
- ZNF665 | c.165C>G p.L55= (on ENST00000600412; = p.L120= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV101128404; called by muse, mutect2, varscan2
- ZNF768 | c.1464C>T p.A488= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs201223902, COSV63323586; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504614 A>G | 5'Flank (SNP) | VAF 5/36 reads (14%) | catalogued as rs768086860; called by muse, mutect2, varscan2
- LEFTY1 | c.*2C>A | 3'UTR (SNP) | VAF 24/115 reads (21%) | catalogued as COSV99686533; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.591A>T | RNA (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.3373C>T | RNA (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100022542; called by muse, mutect2
- ZNF658B | n.2365A>T | RNA (SNP) | VAF 27/71 reads (38%) | called by mutect2, varscan2
